Surgical pathology report (de-identified scan), TCGA case TCGA-G4-6314, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-G4-6314-01A (Primary Tumor).

[page 1 of 2]
SPECIMENS:

- A. RIGHT COLON
- B. PERITONEAL BX

SPECIMEN(S):

- A. RIGHT COLON
- B. PERITONEAL BX

GROSS DESCRIPTION:

A. RIGHT COLON, HEMICOLECTOMY:

Received in fresh state labeled with patient's name and identification number and labeled as "right colon". The specimen consists of a right hemicolectomy specimen. It consists of the ascending colon, measuring 15 cm in length and with internal circumference ranging from 7.5 to 11.0 cm, attached terminal ileum measuring 6 cm in length and with internal circumference of 4 cm. A firm palpable mass is identified along the cecal area which shows a circumferential exophytic ulcerated tumor mass measuring 5.5 x 4.0 x 3.0 cm which grossly involves the ileocecal valve and on section grossly extends into the peri-cecal fat. A small 0.4 cm polyp seen 3 cm from the ileocecal valve and 0.6 cm polyp located 7 cm from the distal resected margin and 7.5 cm from the ileocecal valve. The appendix is not identified and the mucosa of ascending colon shows no other identifiable tumor focus. Multiple sections are submitted and labeled as follows:

- A1: sections from polyp #1, 3 cm from the ileocecal valve area
- A2: second polyp located 7 cm from the distal margin and 7.5 cm from the ileocecal valve
- A3: section from the proximal margin
- A4: section from the distal margin
- A5-A6: en bloc section of cecum, with tumor
- A7-A8: en bloc section of cecal mass
- A9-A10: additional sections from the tumor
- A11: adjacent normal mucosa
- A12-A13: possible six lymph nodes from the cecal region
- A14: five possible lymph nodes near the cecal area
- A15-A18: one lymph node sections from peri-cecal fatty tissue
- A19-A25: one lymph node around tumor area
- A26: sections of lymph nodes distal mid segment of the ascending colon
- A27-A34: sections of lymph nodes from ascending colon
- A35-37 lymphnodes.

B. PERITONEAL BIOPSY

Received in formalin is an unoriented piece of pink-tan soft tissue measuring 1.6 x 1.2 x 0.5 cm. The surface has a powder-burn appearance. Specimen is bisected and submitted entirely in cassette B1.

DIAGNOSIS:

A. RIGHT COLON, RIGHT HEMICOLECTOMY:

- CIRCUMFERENTIAL, EXOPHYTIC, ULCERATED, INVASIVE, MODERATELY TO POORLY DIFFERENTIATED ADENOCARCINOMA OF CECUM WITH EXTENSION TO ILEOCECAL VALVE WITH FULL MUSCLE WALL THICKNESS INVASION AND EXTENSION TO PERICOLIC FAT (WITH LYMPHOVASCULAR INVASION) AND METASTASIS TO FIFTY OUT OF FIFTY-NINE PERICOLIC LYMPH NODES, WITH PERINODAL FAT EXTENSION (50/59) AND WITH TUMOR IMPLANTS.
- SIZE OF TUMOR – 5.5 X 4.0 X 3.0 CM.
- TUBULOVILLOUS ADENOMA (0.6 CM.), 7.0 CM FROM THE DISTAL MARGIN,
- 0.4 CM POLYPOID ADENOCARCINOMA WITH SUBMUCOSAL EXTENSION (3.0 cm from ileocecal valve, ? SATELLITE).
- PROXIMAL AND DISTAL MARGINS OF THE SECTIONS ARE NEGATIVE.
- SEE NOTE.

Note: The appendix is not identified. Metastatic tumor to lymph nodes shows areas of necrosis and calcification and there is lymphovascular invasion.

B. PERITONEAL BIOPSY:

- POSITIVE FOR ADENOCARCINOMA.

[page 2 of 2]
SYNOPTIC REPORT - COLON & RECTUM

Specimens Involved

Specimens: A: RIGHT COLON

B: PERITONEAL BX

Specimen Type: Right hemicolectomy

Tumor Site: Cecum

Tumor Configuration: Exophytic (polypoid)

Infiltrative

Ulcerating

Tumor size: 5.5cm Additional dimensions 4cm x 3cm

WHO Classification

Adenocarcinoma 8140/3

Histologic Grade: G2: Moderately differentiated

Comment(s): (G2; G3)

Extent of Invasion: Lamina propria

Submucosa

Muscularis propria

Subserosa

Margins: Margin(s) uninvolved by invasive carcinoma (Proximal, Distal, Radial)

Venous/Lymphatic Invasion: Present

Perineural Invasion: Absent

Additional Pathologic Findings: Adenoma

Comment(s): (tubulovillous adenoma)

Extent of Resection: R0: Complete resection with grossly and microscopically negative margins

Lymph Nodes: Positive 50 / 59

Extranodal extension: Present

Implants: Present

Implants: pericolic fat

Pathological Staging (pTNM): pT 3 N 2 M 1

CLINICAL HISTORY:

None given

PRE-OPERATIVE DIAGNOSIS:

Cecal cancer

Source: NCI Genomic Data Commons file bfdb740a-db0c-481a-b503-def2d7621ca3 (TCGA-G4-6314.41244014-BB57-45AA-B666-4315F0C2E376.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).